Somatic mutation profile of tumor specimen TCGA-AA-3821-01A (aliquot TCGA-AA-3821-01A-01W-0995-10) from TCGA case TCGA-AA-3821, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 81.3 years (29,706 days).
Specimen TCGA-AA-3821-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 542f529c-02ea-4351-86d1-c52f5fd82c88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3821-10A (Blood Derived Normal), aliquot TCGA-AA-3821-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0335db34-bd5e-4aa1-9f33-d2ef464e1900

The open-access MAF lists 957 somatic variants for this specimen: 729 protein-altering or splice-affecting, 214 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 513, Silent 214, Frame Shift Del 129, Nonsense Mutation 37, Frame Shift Ins 32, Splice Site 6, Splice Region 6, Intron 5, RNA 5, In Frame Del 5, 3'UTR 3, In Frame Ins 1.

Variants (750 of 957; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- C6 | c.2450A>C p.K817T | Missense Mutation (SNP) | VAF 113/253 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV54704910, COSV54705322; called by muse, mutect2, varscan2
- CTSF | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as rs375562245, COSV59747735; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGA | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909606, CM100506, CM930249, COSV57393361; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- LDLR | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs776421777, CM127580, CM960928, COSV52941901; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MYO6 | c.2751del p.K917Nfs*10 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs551348450; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- NOTCH3 | c.3091C>T p.R1031C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.773); catalogued as rs1285584068, CM971070, COSV54628005; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 78/175 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 68/160 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SH3TC2 | c.3511C>T p.R1171C | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759785462, CM136520, COSV60461323; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AASDHPPT | c.878A>T p.D293V | Missense Mutation (SNP) | VAF 43/405 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV53788381, COSV99593295; called by muse, mutect2, varscan2
- ABCA5 | c.742del p.I248* | Frame Shift Del (DEL) | VAF 28/62 reads (45%) | catalogued as rs751460805, COSV67017665; called by mutect2, varscan2
- ABR | c.2192C>A p.P731Q (on ENST00000302538 / NM_021962.5; = p.P694Q on NM_001092.5) | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52142323; called by muse, mutect2, varscan2
- ABR | c.1216C>T p.R406C (on ENST00000302538 / NM_021962.5; = p.R369C on NM_001092.5) | Missense Mutation (SNP) | VAF 16/347 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763390696, COSV99347581; called by muse, mutect2
- ACIN1 | c.4021C>T p.R1341C | Missense Mutation (SNP) | VAF 114/289 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as rs1354967809, COSV52976941; called by muse, mutect2, varscan2
- ACOT12 | c.485G>A p.S162N | Missense Mutation (SNP) | VAF 203/574 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs753320206, COSV56893041; called by muse, mutect2, varscan2
- ACSM2B | c.1550C>G p.S517C | Missense Mutation (SNP) | VAF 290/788 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV61657009, COSV61659260; called by muse, mutect2, varscan2
- ACTBL2 | c.748A>G p.T250A | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.114); catalogued as COSV70661049; called by muse, mutect2, varscan2
- ACTR8 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 114/1303 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1452684482, COSV51635281; called by muse, mutect2
- ACVR2B | c.813C>A p.G271= | Splice Region (SNP) | VAF 39/97 reads (40%) | catalogued as COSV61701452; called by muse, mutect2, varscan2
- ADAM30 | c.1768G>T p.G590C | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65560485; called by muse, mutect2, varscan2
- ADAMTS8 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs771693532, COSV57291770; called by muse, mutect2, varscan2
- ADARB1 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV100653637; called by muse, varscan2
- ADCY10 | c.3063dup p.P1022Sfs*2 | Frame Shift Ins (INS) | VAF 149/598 reads (25%) | catalogued as rs764365704; called by mutect2, pindel, varscan2
- ADGRB3 | c.2888C>G p.A963G | Missense Mutation (SNP) | VAF 570/1534 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53236562, COSV53247358; called by muse, mutect2, varscan2
- ADGRB3 | c.3557C>A p.T1186K | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV53236576; called by muse, mutect2, varscan2
- ADGRF2 | c.1726G>T p.A576S (on ENST00000296862 / NM_001368115.2; = p.A508S on NM_153839.7) | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV57286835; called by mutect2, varscan2
- ADGRG3 | c.161G>A p.C54Y | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59650347; called by muse, mutect2, varscan2
- ADGRG6 | c.839C>A p.T280N | Missense Mutation (SNP) | VAF 32/1070 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV51597800; called by muse, mutect2
- ADSL | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 286/474 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.368); catalogued as rs752238667, COSV53406521; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AEBP1 | c.2905G>A p.V969I | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV56255828; called by muse, varscan2
- AFF3 | c.3029C>A p.S1010* | Nonsense Mutation (SNP) | VAF 298/684 reads (44%) | catalogued as COSV57842940, COSV57859628; called by muse, mutect2, varscan2
- AGBL2 | c.268A>T p.I90L | Missense Mutation (SNP) | VAF 30/654 reads (5%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs1222701409, COSV54090428; called by muse, mutect2
- AGTR2 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 104/264 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1556673748, COSV64156207; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP12 | c.3085G>A p.V1029I | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as rs769872883, COSV53569723; called by muse, mutect2, varscan2
- ALAS1 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV59627005; called by muse, varscan2
- ALDH1B1 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752017437, COSV66619329; called by muse, mutect2
- ALDOB | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV66397426; called by muse, mutect2
- ALPK2 | c.1120T>C p.C374R | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV64490710; called by muse, mutect2, varscan2
- ALYREF | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.516); catalogued as rs1293739168, COSV58668867; called by muse, mutect2, varscan2
- AMOTL1 | c.1015C>A p.P339T | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.129); catalogued as COSV54414424; called by muse, mutect2
- ANAPC7 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 26/163 reads (16%) | catalogued as COSV71443738; called by muse, mutect2, varscan2
- ANK1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1445952603, COSV55874935; called by muse, mutect2, varscan2
- ANKRD11 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753840915, COSV56356157; called by muse, mutect2, varscan2
- ANKRD40 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 301/683 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.541); catalogued as COSV53332880; called by muse, mutect2, varscan2
- ANKS1B | c.902A>T p.D301V | Missense Mutation (SNP) | VAF 274/763 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as COSV61337628; called by muse, mutect2, varscan2
- ANXA10 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 54/496 reads (11%) | catalogued as rs917715269, COSV63738218, COSV63740310; called by muse, mutect2, varscan2
- APBA1 | c.1990G>T p.G664* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV55222639; called by muse, mutect2, varscan2
- APCDD1 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs374082304; called by muse, mutect2, varscan2
- APLP1 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs200771936, COSV55701978; called by muse, mutect2, varscan2
- ARAP2 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs749795521, COSV58283421; called by muse, mutect2, varscan2
- ARFGEF2 | c.3808G>C p.A1270P | Missense Mutation (SNP) | VAF 14/265 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100904079; called by muse, mutect2
- ARHGAP26 | c.1837+1G>A p.X613_splice | Splice Site (SNP) | VAF 72/198 reads (36%) | catalogued as rs1427468777, COSV50832069; called by muse, mutect2, varscan2
- ARHGAP29 | c.3578G>T p.G1193V | Missense Mutation (SNP) | VAF 154/400 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV53109062; called by muse, mutect2, varscan2
- ARHGAP5 | c.2676del p.F892Lfs*9 | Frame Shift Del (DEL) | VAF 43/140 reads (31%) | catalogued as rs781483073; called by mutect2, pindel, varscan2
- ARHGEF25 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs752298345, COSV54084825; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | catalogued as rs758608743; called by mutect2, varscan2
- ARL11 | c.198dup p.Q67Afs*27 | Frame Shift Ins (INS) | VAF 16/47 reads (34%) | catalogued as rs1324509298; called by mutect2, varscan2
- ARL2BP | c.14_16del p.E5del | In Frame Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs764360532; called by mutect2, pindel, varscan2
- ART4 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 247/681 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as COSV57451186; called by muse, mutect2, varscan2
- ASTE1 | c.1412A>G p.Y471C | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV53907787; called by muse, mutect2, varscan2
- ATP1A4 | c.2164G>T p.G722C | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63625686; called by muse, mutect2, varscan2
- ATP8B4 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 641/1743 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52710395; called by muse, mutect2, varscan2
- B3GNT9 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs759175026, COSV54626111; called by muse, mutect2, varscan2
- B3GNT9 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs532297268, COSV54626112; called by muse, mutect2, varscan2
- B4GALT1 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 211/705 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.711); catalogued as rs750802296, COSV65707576; called by muse, mutect2, varscan2
- BBS12 | c.1814A>G p.N605S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100044833; called by muse, mutect2, varscan2
- BCO2 | c.1694C>A p.P565H | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63062689; called by muse, mutect2, varscan2
- BEST1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs765385264, COSV57120026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BIRC3 | c.1414G>A p.G472R | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs145025961; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 10/103 reads (10%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel
- BRD2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66372606; called by muse, mutect2, varscan2
- BRD2 | c.1444A>G p.S482G | Missense Mutation (SNP) | VAF 104/239 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs1561950815, COSV66372613; called by muse, mutect2, varscan2
- BRSK1 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV58665011; called by muse, mutect2, varscan2
- BRWD1 | c.2659C>T p.R887* | Nonsense Mutation (SNP) | VAF 109/244 reads (45%) | catalogued as COSV60893290; called by muse, mutect2, varscan2
- BZW1 | c.854dup p.N285Kfs*54 | Frame Shift Ins (INS) | VAF 37/106 reads (35%) | catalogued as rs774640795; called by mutect2, varscan2
- C11orf80 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs371552584; called by muse, mutect2, varscan2
- C18orf54 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55617474; called by muse, mutect2, varscan2
- C22orf23 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 202/411 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.187); catalogued as COSV50777713; called by muse, mutect2, varscan2
- CACNA1B | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 55/422 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292500359, COSV53112128; called by muse, mutect2, varscan2
- CACNA2D4 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV54945756; called by muse, mutect2, varscan2
- CACNG4 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 114/250 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453288345, COSV50924260; called by muse, mutect2, varscan2
- CAMK1G | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 116/307 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV50520400; called by muse, mutect2, varscan2
- CAPZA1 | c.847A>G p.M283V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV54144419; called by muse, mutect2, varscan2
- CASP5 | c.1096+1G>A p.X366_splice | Splice Site (SNP) | VAF 230/636 reads (36%) | catalogued as rs141481245; called by muse, mutect2, varscan2
- CATSPERE | c.1101G>C p.K367N | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.663); catalogued as COSV63676448; called by muse, mutect2, varscan2
- CCDC106 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs367901327, COSV54401372; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 42/96 reads (44%) | catalogued as rs756347761; called by mutect2, varscan2
- CCSER1 | c.1753G>A p.V585I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs777732218, COSV100388665; called by muse, varscan2
- CCT6B | c.820del p.I274* | Frame Shift Del (DEL) | VAF 40/382 reads (10%) | catalogued as COSV58489395; called by mutect2, varscan2
- CD164L2 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV64995506; called by muse, mutect2, varscan2
- CD200R1 | c.127G>A p.A43T (on ENST00000471858 / NM_170780.3; = p.A66T on NM_138806.4) | Missense Mutation (SNP) | VAF 998/2518 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs776810990, COSV55599510; called by muse, varscan2
- CD6 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 64/149 reads (43%) | catalogued as COSV57836176; called by muse, mutect2, varscan2
- CD79B | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs114330958; ClinVar: uncertain significance; called by muse, mutect2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 163/510 reads (32%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDH1 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 204/499 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.238); catalogued as rs1555515742, COSV55728579, COSV55745612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH10 | c.2306del p.G769Afs*7 | Frame Shift Del (DEL) | VAF 165/485 reads (34%) | catalogued as COSV52582403; called by mutect2, pindel, varscan2
- CDH18 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 168/412 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56900144; called by muse, varscan2
- CDH6 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 23/166 reads (14%) | catalogued as COSV54065281; called by muse, mutect2, varscan2
- CDHR4 | c.401C>A p.P134Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV58525831; called by muse, mutect2, varscan2
- CDON | c.3295G>A p.A1099T | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV54995594; called by muse, mutect2, varscan2
- CELF2 | c.1498C>T p.R500C (on ENST00000416382 / NM_001025077.3; = p.R513C on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV59970271; called by muse, mutect2, varscan2
- CELF4 | c.1085T>C p.I362T | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV58447876; called by muse, mutect2, varscan2
- CEP350 | c.6232del p.R2078Gfs*6 | Frame Shift Del (DEL) | VAF 82/235 reads (35%) | catalogued as rs759430139; called by mutect2, pindel, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 23/68 reads (34%) | catalogued as rs768479535; called by mutect2, pindel, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 28/140 reads (20%) | catalogued as rs761800837; called by mutect2, varscan2
- CFAP43 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 32/386 reads (8%) | catalogued as COSV99530457; called by muse, mutect2
- CFH | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 67/548 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as rs776887716, COSV62776453; called by muse, mutect2, varscan2
- CHD1 | c.3313G>A p.E1105K | Missense Mutation (SNP) | VAF 201/529 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52337881; called by muse, mutect2, varscan2
- CHD4 | c.3491G>A p.R1164H (on ENST00000357008 / NM_001363606.2; = p.R1177H on NM_001273.5) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV58895948; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs751548647; called by mutect2, varscan2
- CHST10 | c.275G>T p.C92F | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs572773940, COSV51804392; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 50/116 reads (43%) | catalogued as rs752250702; called by mutect2, varscan2
- CKMT2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs548849398, COSV54172310; called by muse, mutect2, varscan2
- CLP1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.739); catalogued as COSV100239763; called by muse, mutect2
- CLPP | c.17T>A p.L6* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV55536212; called by muse, mutect2, varscan2
- CLUH | c.1715C>T p.P572L (on ENST00000435359; = p.P610L on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs374090140; called by muse, mutect2, varscan2
- CLUH | c.668G>A p.W223* (on ENST00000435359; = p.W261* on NM_015229.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV70927993; called by muse, mutect2, varscan2
- CNBD1 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 90/245 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV73072562, COSV73073485; called by muse, varscan2
- CNBD1 | c.1026dup p.F343Ifs*21 | Frame Shift Ins (INS) | VAF 158/492 reads (32%) | catalogued as rs747458334; called by pindel, varscan2
- CNDP2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.171); catalogued as rs149206732; called by muse, mutect2, varscan2
- CNTN4 | c.453A>G p.G151= | Splice Region (SNP) | VAF 107/307 reads (35%) | catalogued as COSV68564703; called by muse, mutect2, varscan2
- COL11A2 | c.4558C>T p.R1520C (on ENST00000341947 / NM_080680.3; = p.R1413C on NM_080679.2) | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs934714603, COSV59494192; called by muse, mutect2, varscan2
- COL12A1 | c.5092A>T p.M1698L | Missense Mutation (SNP) | VAF 182/447 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV59390838; called by muse, varscan2
- COL13A1 | c.1550del p.P517Qfs*9 (on ENST00000398978 / NM_001130103.2; = p.P460Qfs*9 on NM_080798.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs770933186, COSV100637433; called by mutect2, pindel, varscan2
- COL1A1 | c.3542G>A p.G1181D | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV56802977; called by muse, mutect2, varscan2
- COL1A1 | c.3058G>A p.A1020T | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.04); catalogued as COSV56802985; called by muse, mutect2, varscan2
- COL25A1 | c.1488del p.G497Efs*14 | Frame Shift Del (DEL) | VAF 234/576 reads (41%) | catalogued as COSV101211681; called by mutect2, pindel, varscan2
- COL5A1 | c.4750C>T p.R1584W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758378927, COSV100879774; called by mutect2, varscan2
- COLEC10 | c.309del p.G104Vfs*39 | Frame Shift Del (DEL) | VAF 86/272 reads (32%) | catalogued as rs1380852549, COSV60521358; called by mutect2, pindel, varscan2
- COLEC11 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780443106, COSV52591898; called by muse, mutect2, varscan2
- COLGALT2 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 30/359 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753492954, COSV62298681; called by muse, mutect2
- COMMD10 | c.570G>T p.K190N | Missense Mutation (SNP) | VAF 168/668 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as COSV57234309; called by muse, mutect2, varscan2
- CPE | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1235670045, COSV68579489; called by muse, mutect2, varscan2
- CRACR2A | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 78/234 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.143); catalogued as rs1301179123, COSV52910710, COSV52911653; called by muse, mutect2, varscan2
- CRMP1 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61478501; called by muse, mutect2, varscan2
- CRYGA | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.143); catalogued as rs143962326; called by muse, mutect2
- CSF1R | c.1108del p.R370Afs*2 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | catalogued as COSV53835903; called by mutect2, varscan2
- CSF2RA | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs777638014, COSV62623722; called by muse, mutect2, varscan2
- CSMD3 | c.1582C>T p.R528W (on ENST00000297405 / NM_001363185.1; = p.R424W on NM_052900.3) | Missense Mutation (SNP) | VAF 98/269 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138791171; called by muse, mutect2, varscan2
- CSNK1A1L | c.690dup p.Q231Tfs*4 | Frame Shift Ins (INS) | VAF 17/64 reads (27%) | catalogued as rs369743261; called by mutect2, varscan2
- CSNK1D | c.293G>T p.R98M | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53923161; called by muse, mutect2, varscan2
- CSRNP2 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1354742242, COSV50396765; called by muse, mutect2, varscan2
- CUX1 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1554531735, COSV52892698; called by muse, mutect2, varscan2
- CYP2C19 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 626/1729 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs56337013, CM983295, COSV64906987; ClinVar: other / drug response; called by muse, mutect2, varscan2
- CYP4A22 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 236/568 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53738575, COSV53741081; called by muse, mutect2, varscan2
- CYTH1 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 141/433 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs770347515, COSV63118785; called by muse, mutect2, varscan2
- DACH1 | c.47del p.P16Lfs*178 | Frame Shift Del (DEL) | VAF 37/93 reads (40%) | catalogued as rs1281799037, COSV100499077; called by mutect2, pindel, varscan2
- DBP | c.874_876del p.K292del | In Frame Del (DEL) | VAF 21/45 reads (47%) | catalogued as rs1447833678; called by mutect2, pindel, varscan2
- DCAF12L2 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs1438264738, COSV63580572; called by muse, mutect2, varscan2
- DCAF4L2 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs780981376, COSV100151233, COSV60476833; called by muse, mutect2, varscan2
- DCC | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs112433088, COSV59087894; called by muse, mutect2, varscan2
- DCLK2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 145/366 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs766290066, COSV56200418; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX6 | c.716A>G p.H239R | Missense Mutation (SNP) | VAF 196/404 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV50587785; called by muse, mutect2, varscan2
- DEF6 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as COSV57353347; called by muse, mutect2, varscan2
- DHCR7 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs151170252; called by muse, mutect2, varscan2
- DHX30 | c.1505G>T p.R502L (on ENST00000445061 / NM_138615.3; = p.R463L on NM_014966.3) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53135856; called by muse, mutect2
- DHX38 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as rs1385706449, COSV51696590; called by muse, mutect2, varscan2
- DHX38 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs753722533, COSV51696673; called by muse, mutect2, varscan2
- DIDO1 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as rs971238235, COSV56615383; called by muse, mutect2, varscan2
- DIS3L | c.785G>A p.R262Q (on ENST00000319212 / NM_001143688.3; = p.R179Q on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 142/426 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs372960179; called by muse, mutect2, varscan2
- DKK1 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.15); catalogued as rs746154609, COSV64759996; called by muse, mutect2
- DLX3 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs766585893, COSV71547493; called by muse, varscan2
- DNAH3 | c.7313G>A p.S2438N | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54507000; called by muse, mutect2, varscan2
- DNAH7 | c.1745T>C p.V582A | Missense Mutation (SNP) | VAF 233/549 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV56754270; called by muse, mutect2, varscan2
- DNAJB11 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs745390980, COSV54001998; called by muse, mutect2, varscan2
- DOCK10 | c.6397C>T p.H2133Y | Missense Mutation (SNP) | VAF 328/853 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV51353161, COSV99289718; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 1031/1444 reads (71%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOK5 | c.830G>A p.S277N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.827); catalogued as COSV52817321, COSV52819853; called by muse, mutect2, varscan2
- DOP1B | c.6031A>G p.N2011D | Missense Mutation (SNP) | VAF 524/1390 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV67692328; called by muse, mutect2, varscan2
- DPP10 | c.1612C>A p.L538I | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59668320, COSV59700483; called by muse, mutect2, varscan2
- DPP4 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 205/505 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV62105399; called by muse, mutect2, varscan2
- DPYS | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 223/525 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1241540663, COSV60906826; called by muse, mutect2, varscan2
- DPYSL3 | c.1545del p.A516Qfs*15 | Frame Shift Del (DEL) | VAF 28/107 reads (26%) | catalogued as COSV58330771; called by mutect2, pindel, varscan2
- DSCAML1 | c.1525G>A p.V509M (on ENST00000321322; = p.V449M on NM_020693.4) | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs777936134, COSV58383345; called by muse, mutect2, varscan2
- DSCAML1 | c.400C>T p.R134W (on ENST00000321322; = p.R74W on NM_020693.4) | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339097046, COSV58383358; called by muse, mutect2, varscan2
- DST | c.11422G>A p.G3808R (on ENST00000361203 / NM_001374722.1; = p.G1396R on NM_015548.5) | Missense Mutation (SNP) | VAF 1035/2470 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs540399392, COSV55000818; called by muse, varscan2
- DUSP9 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.707); catalogued as rs781805190, COSV61437815; called by muse, mutect2, varscan2
- DZIP3 | c.2723C>T p.A908V | Missense Mutation (SNP) | VAF 212/523 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs147602420; called by muse, mutect2, varscan2
- E2F7 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 143/329 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs776161589, COSV59737781; called by muse, mutect2, varscan2
- E2F8 | c.2473C>T p.R825C | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs375220543, COSV51462201; called by muse, mutect2, varscan2
- EDNRB | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV57523779; called by muse, mutect2, varscan2
- EGF | c.2648del p.P883Lfs*67 | Frame Shift Del (DEL) | VAF 128/592 reads (22%) | catalogued as rs758373637; called by mutect2, varscan2
- EGFL6 | c.748G>T p.G250* | Nonsense Mutation (SNP) | VAF 88/229 reads (38%) | catalogued as COSV63633022; called by muse, mutect2, varscan2
- EGFL8 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376635812; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 198/1149 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs868360610, COSV57514831; called by muse, mutect2, varscan2
- ELF1 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1327553855, COSV53497367; called by muse, mutect2, varscan2
- EOGT | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55149700; called by muse, mutect2, varscan2
- EPHX1 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs141221713; called by muse, mutect2, varscan2
- EPN1 | c.833del p.G278Afs*164 (on ENST00000270460 / NM_001321263.1; = p.G253Afs*163 on NM_013333.3) | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs755604942; called by mutect2, varscan2
- ERCC2 | c.68_70del p.S23del | In Frame Del (DEL) | VAF 33/96 reads (34%) | catalogued as rs886054500; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- EYA4 | c.790A>G p.S264G | Missense Mutation (SNP) | VAF 127/346 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as rs1392356186, COSV62046795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F9 | c.46A>G p.T16A | Missense Mutation (SNP) | VAF 375/932 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV54378937; called by muse, mutect2, varscan2
- FAM118A | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779065900, COSV53415931, COSV99343292; called by muse, varscan2
- FAM135B | c.4105G>A p.A1369T | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52709117, COSV52732702; called by muse, mutect2, varscan2
- FAM20A | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as COSV99873489; called by mutect2, varscan2
- FAM71F2 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 166/418 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV101100669, COSV66351978; called by muse, mutect2, varscan2
- FBXO5 | c.1017del p.D340Mfs*30 | Frame Shift Del (DEL) | VAF 201/634 reads (32%) | catalogued as rs1292004982; called by mutect2, pindel, varscan2
- FCRL1 | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100839736; called by muse, mutect2
- FGD2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as rs772703341, COSV51462518, COSV51466659; called by muse, mutect2, varscan2
- FGFR2 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100335502, COSV60662820; called by muse, mutect2
- FGFR4 | c.1840G>T p.A614S | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52801489; called by muse, mutect2, varscan2
- FIG4 | c.2714G>A p.R905H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as rs780921285, COSV100019281; called by muse, mutect2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 162/462 reads (35%) | catalogued as rs752076602; called by mutect2, pindel, varscan2
- FLT4 | c.3668G>A p.R1223H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs373742042; called by muse, mutect2, varscan2
- FMR1NB | c.335A>G p.H112R | Missense Mutation (SNP) | VAF 106/828 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs782246735, COSV63272686; called by muse, varscan2
- FNDC1 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); catalogued as rs756004336, COSV51932050; called by muse, mutect2, varscan2
- FOXA3 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs764817302, COSV56215129; called by muse, mutect2, varscan2
- FOXN3 | c.1019C>A p.A340D (on ENST00000261302; = p.A318D on NM_005197.4) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV54304829; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs760347049; called by mutect2, varscan2
- FOXP4 | c.1246G>A p.A416T (on ENST00000307972 / NM_001012426.1; = p.A403T on NM_138457.3) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767113603, COSV57218543; called by muse, mutect2, varscan2
- FRMPD1 | c.2840G>A p.R947Q | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as rs373579365; called by muse, mutect2, varscan2
- FRYL | c.8161T>C p.F2721L | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as COSV51941124; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 106/334 reads (32%) | catalogued as rs756304971; called by mutect2, varscan2
- GABBR1 | c.1541A>G p.N514S | Missense Mutation (SNP) | VAF 57/1246 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV100589502; called by muse, mutect2
- GABRE | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs553890653, COSV64819053; called by muse, mutect2, varscan2
- GABRG1 | c.1381G>T p.G461C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as COSV54950653, COSV54950897; called by muse, mutect2, varscan2
- GALNS | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as rs779257235, COSV51935975; called by muse, mutect2, varscan2
- GALNT10 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs146720050; called by muse, mutect2, varscan2
- GALNT11 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 279/693 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs771748654, COSV57424769; called by muse, mutect2, varscan2
- GATA3 | c.431del p.G144Afs*51 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as COSV60516711; called by mutect2, pindel, varscan2
- GATA3 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM051043, CM1514397, COSV60516059; called by muse, mutect2, varscan2
- GBP4 | c.908C>G p.T303S | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV63253171; called by muse, mutect2, varscan2
- GCC2 | c.4874A>C p.Q1625P | Missense Mutation (SNP) | VAF 170/1032 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV59174418; called by muse, mutect2, varscan2
- GDF11 | c.1120C>A p.P374T | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57689328; called by muse, mutect2, varscan2
- GGTLC1 | c.279del p.S94Hfs*58 | Frame Shift Del (DEL) | VAF 34/111 reads (31%) | catalogued as rs753146433; called by mutect2, pindel, varscan2
- GHSR | c.587A>T p.N196I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as COSV53837748; called by muse, mutect2, varscan2
- GJC2 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64512435; called by muse, mutect2, varscan2
- GLE1 | c.1930A>C p.M644L | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778694188, COSV59406634; called by muse, mutect2, varscan2
- GLRA2 | c.34T>A p.L12M | Missense Mutation (SNP) | VAF 132/382 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV54336659; called by muse, mutect2, varscan2
- GMPR | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV99439862; called by muse, mutect2
- GNA14 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 112/339 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.018); catalogued as COSV59019449; called by muse, mutect2, varscan2
- GNRH1 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1336171284, CM162730, COSV99373591; called by muse, mutect2
- GPR162 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50589309; called by muse, mutect2, varscan2
- GRIK3 | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1039838704, COSV66136255; called by mutect2, varscan2
- GRM5 | c.2774G>T p.R925L (on ENST00000305447 / NM_001143831.2; = p.R893L on NM_000842.4) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); catalogued as COSV59588578, COSV59593630, COSV59599340; called by muse, mutect2, varscan2
- GRPEL1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs766058514, COSV53826820; called by muse, mutect2, varscan2
- GSK3B | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 520/1391 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51771447; called by muse, mutect2, varscan2
- GTPBP1 | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV99322986; called by muse, mutect2, varscan2
- GUCY2C | c.1336C>T p.L446F | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1244861414, COSV53787480; called by muse, mutect2, varscan2
- H2BC6 | c.179T>C p.M60T | Missense Mutation (SNP) | VAF 176/226 reads (78%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.095); catalogued as rs764300457, COSV61590774; called by muse, mutect2, varscan2
- HACE1 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 192/527 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.931); catalogued as rs781480828, COSV53499697; called by muse, mutect2, varscan2
- HAS1 | c.735G>T p.M245I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.216); catalogued as COSV55786450; called by muse, mutect2, varscan2
- HECTD1 | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101237316; called by muse, mutect2
- HECTD4 | c.6208C>T p.R2070C | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66387681; called by muse, mutect2, varscan2
- HELQ | c.2303C>T p.T768M | Missense Mutation (SNP) | VAF 104/302 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs1355172192, COSV55024323; called by muse, mutect2, varscan2
- HELT | c.431A>T p.D144V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV58819696; called by muse, mutect2, varscan2
- HLX | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV65044406; called by muse, mutect2, varscan2
- HPS6 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 29/55 reads (53%) | catalogued as COSV54624981; called by muse, mutect2, varscan2
- HRH2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 189/475 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51573110; called by muse, mutect2, varscan2
- HSPG2 | c.5356G>A p.G1786R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766592389, COSV65969505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHD6-13 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 50/126 reads (40%) | catalogued as rs575338017; called by muse, varscan2
- IGSF3 | c.1552C>T p.R518W (on ENST00000369486 / NM_001007237.3; = p.R538W on NM_001542.4) | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs768695435, COSV59587457; called by muse, mutect2, varscan2
- IKBKE | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as COSV65626582; called by muse, mutect2, varscan2
- IL2RB | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 68/112 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV53425148; called by muse, mutect2, varscan2
- IQGAP1 | c.2822del p.N941Ifs*8 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | catalogued as rs771739474; called by mutect2, varscan2
- IQGAP3 | c.1010A>G p.Q337R | Missense Mutation (SNP) | VAF 142/359 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV63249908; called by muse, mutect2, varscan2
- IQSEC3 | c.2432G>A p.R811Q (on ENST00000538872 / NM_001170738.2; = p.R508Q on NM_015232.1) | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs782717266, COSV58281392; called by muse, mutect2, varscan2
- ITPRIPL2 | c.170T>A p.L57H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV67347396; called by muse, mutect2, varscan2
- KANSL3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62615983; called by muse, mutect2, varscan2
- KAZN | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV63206939; called by muse, mutect2, varscan2
- KCNA10 | c.734G>T p.R245M | Missense Mutation (SNP) | VAF 87/232 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV63904277; called by muse, mutect2, varscan2
- KCND3 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs761121098, COSV56176281; called by muse, mutect2, varscan2
- KCNJ8 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 109/376 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.173); catalogued as COSV53717835; called by muse, varscan2
- KCTD11 | c.319C>T p.P107S (on ENST00000333751 / NM_001363642.1; = p.P68S on NM_001002914.2) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs1413236034, COSV50134219; called by muse, mutect2
- KEL | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 125/351 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV62333620, COSV62335743; called by muse, mutect2, varscan2
- KHDRBS3 | c.1001C>A p.A334E | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.48); catalogued as COSV63415327; called by muse, mutect2, varscan2
- KIAA0586 | c.3043G>T p.G1015C (on ENST00000619416 / NM_001244190.2; = p.G954C on NM_014749.5) | Missense Mutation (SNP) | VAF 166/442 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV54171955, COSV54177992; called by muse, mutect2, varscan2
- KIAA1109 | c.5873G>A p.R1958Q | Missense Mutation (SNP) | VAF 85/241 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1263871665, COSV52664246; called by muse, mutect2, varscan2
- KIAA1109 | c.5945A>C p.D1982A | Missense Mutation (SNP) | VAF 48/384 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV52664253; called by muse, mutect2, varscan2
- KIAA1109 | c.*4del | Frame Shift Del (DEL) | VAF 25/83 reads (30%) | catalogued as COSV52668349; called by mutect2, pindel, varscan2
- KIF13B | c.1774G>T p.A592S | Missense Mutation (SNP) | VAF 216/578 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73054182, COSV73054682; called by muse, mutect2, varscan2
- KIF20A | c.2423C>T p.A808V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV67509390; called by muse, mutect2, varscan2
- KLHL38 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs780188773, COSV100384445, COSV58086288; called by muse, varscan2
- KLHL41 | c.215del p.K72Rfs*3 | Frame Shift Del (DEL) | VAF 67/192 reads (35%) | catalogued as COSV52930337; called by mutect2, varscan2
- KMT2E | c.1179G>T p.M393I | Missense Mutation (SNP) | VAF 75/1580 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV99995927; called by muse, mutect2
- KPNA1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775027981, COSV60267961; called by muse, mutect2, varscan2
- KPRP | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100908670; called by muse, mutect2, varscan2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 56/272 reads (21%) | catalogued as rs761148574; called by mutect2, varscan2
- KRT4 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs372301476; called by muse, mutect2, varscan2
- KRT75 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 99/223 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as rs780776250, COSV52871208, COSV52871301; called by muse, mutect2, varscan2
- L3MBTL2 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs957321378, COSV53432012; called by muse, mutect2, varscan2
- LAMA3 | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV58063457; called by muse, mutect2, varscan2
- LENG8 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.248); catalogued as rs139078013, COSV58726225; called by muse, mutect2, varscan2
- LEXM | c.784A>T p.M262L | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.124); catalogued as COSV64022208; called by muse, mutect2, varscan2
- LHX6 | c.94G>A p.A32T (on ENST00000373755 / NM_001242334.2; = p.A61T on NM_014368.5) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs1292174061, COSV61343970; called by muse, mutect2, varscan2
- LILRA4 | c.1078del p.A360Qfs*8 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | catalogued as rs765067201, COSV99392953, COSV99392960; called by mutect2, pindel, varscan2
- LIPG | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 108/208 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.21); catalogued as rs750648857, COSV54294741; called by muse, mutect2, varscan2
- LMBRD1 | c.143T>C p.I48T | Missense Mutation (SNP) | VAF 126/362 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.393); catalogued as COSV65296293; called by muse, mutect2, varscan2
- LONRF2 | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 169/417 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs762460147, COSV66539655; called by muse, mutect2, varscan2
- LRBA | c.8565G>A p.W2855* | Nonsense Mutation (SNP) | VAF 20/113 reads (18%) | catalogued as COSV63950779; called by muse, mutect2, varscan2
- LRP2BP | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 24/259 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs765686066, COSV60749431; called by muse, mutect2
- LRRC37A3 | c.4812C>A p.I1604= | Splice Region (SNP) | VAF 70/866 reads (8%) | catalogued as rs765432047, COSV58534435; called by muse, mutect2
- LRRC39 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 81/1096 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs765807301, COSV100734393; called by muse, mutect2
- LRRIQ1 | c.2323G>T p.A775S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.395); catalogued as COSV67826768; called by muse, mutect2, varscan2
- LY75 | c.4235del p.K1412Rfs*2 | Frame Shift Del (DEL) | VAF 85/290 reads (29%) | catalogued as rs1301982151; called by mutect2, pindel, varscan2
- LZTR1 | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as COSV53145592; called by muse, mutect2, varscan2
- LZTR1 | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as rs778337323, COSV53145604; called by muse, mutect2, varscan2
- MACC1 | c.1643T>C p.L548S | Missense Mutation (SNP) | VAF 136/364 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV60541156; called by muse, mutect2, varscan2
- MACROD2 | c.1145-1G>T p.X382_splice (on ENST00000642719; = p.X354_splice on NM_080676.6 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 88/237 reads (37%) | catalogued as COSV53946838, COSV54005874, COSV99428277; called by muse, mutect2, varscan2
- MAGEE1 | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as COSV63909018; called by muse, mutect2, varscan2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | catalogued as rs1159257962; called by mutect2, pindel, varscan2
- MAN1B1 | c.1014dup p.L339Afs*18 | Frame Shift Ins (INS) | VAF 32/76 reads (42%) | catalogued as rs752359237; called by mutect2, varscan2
- MAP3K10 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV53420723; called by mutect2, varscan2
- MAP3K4 | c.2327A>G p.E776G | Missense Mutation (SNP) | VAF 397/1381 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62330573; called by muse, mutect2, varscan2
- MAP3K6 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536088084, COSV62887390, COSV62887825; called by muse, mutect2, varscan2
- MARK1 | c.2036G>C p.S679T | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV65065938; called by muse, mutect2, varscan2
- MBD1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 121/166 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs771787035, COSV53998883; called by muse, mutect2, varscan2
- MCC | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 436/1166 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as rs757596340, COSV56724755; called by muse, mutect2, varscan2
- MCM10 | c.2102del p.N701Tfs*35 (on ENST00000484800 / NM_182751.3; = p.N700Tfs*35 on NM_018518.5) | Frame Shift Del (DEL) | VAF 9/92 reads (10%) | catalogued as rs772561920; called by mutect2, pindel, varscan2
- MCM4 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50621524; called by muse, mutect2, varscan2
- MDN1 | c.7258C>T p.R2420* | Nonsense Mutation (SNP) | VAF 18/166 reads (11%) | catalogued as rs187636155, COSV65518172; called by muse, mutect2, varscan2
- MDN1 | c.6949G>T p.D2317Y | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV65518178, COSV65529459; called by muse, mutect2, varscan2
- MED1 | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV56122781; called by muse, mutect2, varscan2
- MEGF8 | c.659C>A p.A220D | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV52076905; called by muse, mutect2, varscan2
- METTL22 | c.187G>T p.G63* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV50837442; called by muse, mutect2
- MFSD2B | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs531128708, COSV57854033; called by muse, mutect2, varscan2
- MGAM | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs1554457449, COSV71885052; called by muse, mutect2, varscan2
- MICAL1 | c.2259del p.T754Qfs*150 | Frame Shift Del (DEL) | VAF 41/75 reads (55%) | catalogued as COSV57804418; called by mutect2, pindel, varscan2
- MON1B | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1029788096, COSV50245531; called by muse, mutect2, varscan2
- MORF4L1 | c.614C>T p.P205L (on ENST00000331268 / NM_206839.2; = p.P166L on NM_006791.4) | Missense Mutation (SNP) | VAF 140/398 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.221); catalogued as rs988041200, COSV58703958; called by muse, mutect2, varscan2
- MPIG6B | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as rs1266724800, COSV65389381; called by muse, mutect2, varscan2
- MPP2 | c.1282C>T p.R428C (on ENST00000461854 / NM_001278372.2; = p.R404C on NM_005374.5) | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs374234227; called by muse, mutect2, varscan2
- MPP3 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 112/209 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs940616228, COSV101263304, COSV68197399; called by muse, mutect2, varscan2
- MSH5 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs923694243, COSV100994826, COSV65208836; called by muse, mutect2, varscan2
- MSH5 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs772174876; called by muse, mutect2
- MTHFSD | c.62T>C p.M21T (on ENST00000360900 / NM_001159377.2; = p.M20T on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/272 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV59802378; called by muse, mutect2, varscan2
- MTMR3 | c.1813del p.L605* | Frame Shift Del (DEL) | VAF 59/162 reads (36%) | catalogued as COSV60305229; called by mutect2, pindel, varscan2
- MTOR | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.959); catalogued as rs748207893, COSV63868954, COSV63872235; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.37667A>C p.K12556T | Missense Mutation (SNP) | VAF 577/1542 reads (37%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.041); catalogued as COSV67449613; called by muse, mutect2, varscan2
- MUC16 | c.28520C>T p.T9507M | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as rs370765065; called by muse, mutect2, varscan2
- MUC6 | c.6950G>A p.R2317Q | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs757773646, COSV59958396; called by muse, mutect2, varscan2
- MXRA5 | c.7081G>A p.G2361R | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99476060; called by muse, mutect2, varscan2
- MXRA5 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 32/528 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1038611462, COSV99476061; called by muse, mutect2
- MYH10 | c.5819G>A p.R1940Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs370970711; called by muse, mutect2, varscan2
- MYH10 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52595982; called by muse, mutect2, varscan2
- MYH11 | c.2497C>T p.Q833* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as COSV55545103; called by muse, mutect2, varscan2
- MYH4 | c.4157G>A p.R1386H | Missense Mutation (SNP) | VAF 108/270 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs768630081, COSV55113478; called by muse, mutect2, varscan2
- MYL1 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.105); catalogued as rs570955358, COSV61681353; called by muse, mutect2, varscan2
- MYO16 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs1200947622, COSV51780421; called by muse, mutect2, varscan2
- MYO7A | c.1623del p.K542Rfs*80 | Frame Shift Del (DEL) | VAF 42/80 reads (53%) | catalogued as COSV68685202; called by mutect2, varscan2
- MYOCD | c.68G>T p.R23I | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58498321; called by muse, mutect2, varscan2
- N6AMT1 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 291/714 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV58133848; called by muse, mutect2, varscan2
- NAP1L5 | c.462G>C p.E154D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV52020776; called by mutect2, varscan2
- NAV2 | c.4369G>A p.A1457T (on ENST00000396087 / NM_001244963.2; = p.A1434T on NM_145117.5) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765276374, COSV60656997; called by muse, mutect2, varscan2
- NCF4 | c.280T>G p.Y94D | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV50620448; called by muse, mutect2, varscan2
- NCKAP1L | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 310/867 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762520053, COSV53204019; called by muse, mutect2, varscan2
- NCKAP5 | c.2366C>T p.S789L | Missense Mutation (SNP) | VAF 16/582 reads (3%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1364296997; called by muse, mutect2
- NCOA3 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 99/279 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59066286; called by muse, mutect2, varscan2
- NECAB3 | c.1109T>C p.I370T (on ENST00000246190 / NM_031232.4; = p.I336T on NM_031231.4) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV55774994; called by muse, mutect2, varscan2
- NELL1 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 235/715 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV54243180; called by muse, mutect2, varscan2
- NEMP1 | c.655G>A p.V219I (on ENST00000300128 / NM_001130963.2; = p.V146I on NM_015257.3) | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs763305232, COSV55661751; called by muse, mutect2, varscan2
- NID1 | c.2371C>T p.P791S | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV51615825; called by muse, mutect2, varscan2
- NID2 | c.3608C>T p.T1203M | Missense Mutation (SNP) | VAF 96/274 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200641159, COSV53493651; called by muse, mutect2, varscan2
- NLRC5 | c.2870+2T>C p.X957_splice | Splice Site (SNP) | VAF 12/185 reads (6%) | catalogued as COSV99346666; called by muse, mutect2
- NLRP1 | c.3914A>G p.K1305R | Missense Mutation (SNP) | VAF 69/113 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as rs1335969869, COSV52559725; called by muse, mutect2, varscan2
- NME8 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 164/444 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs117675957, COSV52247271; called by muse, mutect2, varscan2
- NME9 | c.223G>A p.E75K (on ENST00000333911 / NM_001349024.2; = p.E53K on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 197/488 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as rs200732318, COSV58616706; called by muse, mutect2, varscan2
- NOC4L | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV57957440; called by muse, mutect2, varscan2
- NOX3 | c.1589T>C p.I530T | Missense Mutation (SNP) | VAF 96/444 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV50149000; called by muse, mutect2, varscan2
- NPAS4 | c.1157C>A p.A386E | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV60649095; called by muse, mutect2, varscan2
- NPY2R | c.1082A>C p.K361T | Missense Mutation (SNP) | VAF 92/263 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100279430, COSV100279910, COSV61527383, COSV61528948; called by muse, mutect2, varscan2
- NR4A2 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59892806, COSV59893515; called by muse, mutect2, varscan2
- NRP2 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55924275; called by muse, mutect2, varscan2
- NRXN1 | c.3134C>A p.A1045D | Missense Mutation (SNP) | VAF 208/596 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV100453940, COSV58439070; called by muse, mutect2, varscan2
- NUF2 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs775293541, COSV54842355; called by muse, mutect2, varscan2
- NUGGC | c.1359G>C p.K453N | Missense Mutation (SNP) | VAF 313/812 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.094); catalogued as COSV58432865; called by muse, varscan2
- NUMBL | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV53284555; called by muse, mutect2, varscan2
- NUP153 | c.3059C>A p.A1020E | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV50446640; called by muse, mutect2, varscan2
- NUP205 | c.4148A>G p.N1383S | Missense Mutation (SNP) | VAF 110/222 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53655684; called by muse, mutect2, varscan2
- NUP85 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.25); catalogued as COSV55463078; called by muse, mutect2, varscan2
- OBSCN | c.7901T>C p.V2634A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.846); catalogued as COSV52747535; called by muse, mutect2, varscan2
- OR10G9 | c.584A>T p.E195V | Missense Mutation (SNP) | VAF 248/552 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs765612944, COSV66685845; called by muse, mutect2, varscan2
- OR11H6 | c.370del p.S124Hfs*31 | Frame Shift Del (DEL) | VAF 35/116 reads (30%) | catalogued as rs762454146; called by mutect2, pindel, varscan2
- OR11L1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63313787; called by muse, mutect2
- OR1E2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs112466079, COSV50265397; called by muse, mutect2, varscan2
- OR2Z1 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV100136358; called by muse, mutect2
- OR51A4 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs758219998, COSV66749144; called by muse, mutect2, varscan2
- OR8K3 | c.475G>C p.V159L | Missense Mutation (SNP) | VAF 90/309 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.02); catalogued as COSV57130928; called by muse, mutect2, varscan2
- ORAI1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs368310115; called by muse, mutect2, varscan2
- OSBPL7 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.1); catalogued as rs759685275, COSV50106733; called by muse, mutect2
- OSMR | c.1849del p.T617Qfs*20 | Frame Shift Del (DEL) | VAF 200/516 reads (39%) | catalogued as rs762315064; called by mutect2, pindel, varscan2
- OTUB2 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 11/161 reads (7%) | catalogued as rs759113013, COSV99180148; called by muse, mutect2
- PABPC3 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.546); catalogued as rs779631565, COSV55798084; called by muse, mutect2, varscan2
- PADI3 | c.1316G>A p.G439D | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV64934068; called by muse, mutect2, varscan2
- PAPOLG | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 102/244 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs1019836388, COSV53181529; called by muse, mutect2, varscan2
- PAPPA | c.3314C>T p.T1105M | Missense Mutation (SNP) | VAF 377/937 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1472615793, COSV60278457, COSV60288225; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 42/135 reads (31%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PCDH1 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as rs201502657, COSV54610999; called by mutect2, varscan2
- PCDH12 | c.2153C>T p.T718M | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs147575499; called by muse, mutect2, varscan2
- PCDH12 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1343525722, COSV51519819; called by muse, mutect2, varscan2
- PCDHA2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV65364438; called by muse, mutect2, varscan2
- PCDHA9 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV65323887; called by muse, mutect2, varscan2
- PCDHB2 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs569244465, COSV50564827; called by muse, mutect2, varscan2
- PCDHGA1 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); catalogued as COSV65295207; called by muse, mutect2, varscan2
- PCDHGA5 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.166); catalogued as rs868142397, COSV53908755; called by muse, mutect2, varscan2
- PCGF6 | c.281A>C p.E94A | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV61494420; called by muse, mutect2, varscan2
- PCK2 | c.1482G>A p.M494I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.208); catalogued as COSV53748155; called by muse, mutect2, varscan2
- PDCD6IP | c.602del p.L201* | Frame Shift Del (DEL) | VAF 83/248 reads (33%) | catalogued as rs781474699; called by mutect2, varscan2
- PDE7A | c.208C>T p.R70C (on ENST00000401827 / NM_001242318.3; = p.R44C on NM_002603.4) | Missense Mutation (SNP) | VAF 116/324 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs774612786, COSV65152346; called by muse, mutect2, varscan2
- PDILT | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 155/1011 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs144890989, COSV56699975; called by muse, mutect2, varscan2
- PDZD2 | c.7010A>G p.Q2337R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56852457; called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV59010473; called by muse, mutect2, varscan2
- PGK2 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV59163028; called by muse, mutect2, varscan2
- PGM1 | c.1534del p.A512Pfs*33 | Frame Shift Del (DEL) | VAF 56/253 reads (22%) | catalogued as COSV64300452; called by mutect2, pindel, varscan2
- PHACTR2 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs770231609, COSV59851069; called by muse, mutect2, varscan2
- PHC1 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746995572, COSV70417613; called by muse, mutect2, varscan2
- PHC1 | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs780042534, COSV50002620; called by muse, mutect2, varscan2
- PHF8 | c.1234C>A p.L412M (on ENST00000357988 / NM_001184896.1; = p.L376M on NM_015107.3) | Missense Mutation (SNP) | VAF 72/256 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV57678050; called by muse, mutect2, varscan2
- PHF8 | c.728C>T p.P243L (on ENST00000357988 / NM_001184896.1; = p.P207L on NM_015107.3) | Missense Mutation (SNP) | VAF 150/367 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57678056; called by muse, mutect2, varscan2
- PIF1 | c.743del p.T248Kfs*34 | Frame Shift Del (DEL) | VAF 23/52 reads (44%) | catalogued as COSV51421120; called by mutect2, pindel, varscan2
- PIK3C2G | c.4444G>T p.G1482* (on ENST00000676171; = p.G1441* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 300/736 reads (41%) | catalogued as COSV56799256, COSV56805954; called by muse, mutect2, varscan2
- PIK3R6 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 211/612 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as rs574711552, COSV61001734; called by muse, mutect2, varscan2
- PIWIL1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 59/147 reads (40%) | catalogued as rs750875858, COSV55344677; called by muse, mutect2, varscan2
- PLA2R1 | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99322373; called by muse, mutect2, varscan2
- PLCH1 | c.1981C>T p.R661C (on ENST00000340059 / NM_001130960.2; = p.R673C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1313996627, COSV58189056; called by muse, mutect2, varscan2
- PLD4 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.349); catalogued as rs543549955, COSV101190461; called by muse, mutect2, varscan2
- PLEKHB1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 221/505 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs754703598, COSV57049058; called by muse, mutect2, varscan2
- PLXNA3 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs138547861; called by muse, mutect2
- PLXND1 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV60709978; called by muse, mutect2, varscan2
- PM20D1 | c.1196T>A p.V399D | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV65648525; called by muse, mutect2, varscan2
- PNMA8A | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV58136002; called by muse, mutect2, varscan2
- PPA2 | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 90/746 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as rs765643758, COSV58993681; called by muse, mutect2, varscan2
- PPCS | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1482478128, COSV65333597; called by muse, mutect2
- PPEF2 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs1429833805, COSV54420586; called by muse, mutect2, varscan2
- PRB3 | c.248del p.P83Hfs*266 (on ENST00000381842; = p.P83Hfs*? on NM_006249.5) | Frame Shift Del (DEL) | VAF 255/872 reads (29%) | catalogued as rs763309024; called by mutect2, pindel, varscan2
- PRDM15 | c.-486T>C | Splice Region (SNP) | VAF 21/62 reads (34%) | catalogued as COSV54149619; called by muse, mutect2, varscan2
- PRKD1 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.216); catalogued as COSV59560705; called by muse, mutect2, varscan2
- PRPF40B | c.2379G>A p.S793= (on ENST00000380281; = p.S780= on NM_012272.3) | Splice Region (SNP) | VAF 81/184 reads (44%) | catalogued as rs1444506902, COSV53298527; called by muse, mutect2, varscan2
- PRPF8 | c.6052G>A p.A2018T | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.418); catalogued as COSV56772825; called by muse, mutect2, varscan2
- PSEN1 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 130/311 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as CM024347, COSV56193253; called by muse, mutect2, varscan2
- PSMB9 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV62753891; called by muse, mutect2, varscan2
- PSMD3 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs138262103, COSV52856649; called by muse, mutect2, varscan2
- PTCH2 | c.203C>A p.A68D | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376362870; called by muse, mutect2, varscan2
- PTK2 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs200017517; called by muse, mutect2, varscan2
- PTN | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 277/567 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV61963624; called by muse, mutect2, varscan2
- PTPN14 | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs754960996, COSV65289826; called by mutect2, varscan2
- PTPRC | c.2180-1G>T p.X727_splice | Splice Site (SNP) | VAF 140/309 reads (45%) | catalogued as COSV100722224; called by muse, mutect2, varscan2
- PTPRN | c.2331G>A p.M777I | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.267); catalogued as COSV55346063; called by muse, mutect2, varscan2
- PTPRN | c.1192A>G p.T398A | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV55346073; called by muse, mutect2, varscan2
- PYCR2 | c.885del p.T296Qfs*5 | Frame Shift Del (DEL) | VAF 160/500 reads (32%) | catalogued as rs1383249693; called by pindel, varscan2
- RAI2 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 240/1301 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100518183; called by muse, mutect2, varscan2
- RALGAPA2 | c.3482C>T p.A1161V | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs763690497, COSV52490135; called by muse, mutect2, varscan2
- RANGRF | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99873753; called by muse, mutect2, varscan2
- RASD2 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as rs758004247, COSV53352088; called by muse, mutect2, varscan2
- RASGRP1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 92/196 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752166771, COSV60363927; called by muse, mutect2, varscan2
- RASSF2 | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV65081760; called by muse, mutect2, varscan2
- RBM33 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56629630; called by muse, mutect2, varscan2
- RBM4 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs765301901, COSV59518195; called by muse, mutect2, varscan2
- RBP4 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383758574, COSV65159696; called by muse, mutect2, varscan2
- RELA | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58013982; called by muse, mutect2, varscan2
- RET | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.014); catalogued as rs570176656, COSV60688178, COSV60694580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFX3 | c.1135T>A p.L379M | Missense Mutation (SNP) | VAF 156/355 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV56509064; called by muse, mutect2, varscan2
- RGS20 | c.527G>A p.R176Q (on ENST00000297313 / NM_170587.4; = p.R29Q on NM_003702.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs761091721, COSV52014370; called by muse, mutect2, varscan2
- RGS3 | c.2743C>T p.R915C (on ENST00000350696 / NM_001282923.2; = p.R634C on NM_130795.4) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs371025710; called by muse, mutect2
- RGS9 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52223457, COSV52226295; called by muse, mutect2, varscan2
- RHBDF2 | c.2356G>A p.A786T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.315); catalogued as rs749683389, COSV51683754; called by muse, mutect2, varscan2
- RIF1 | c.331T>C p.S111P | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV54613246; called by muse, mutect2, varscan2
- RIMBP2 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs778134326, COSV55466438, COSV99074711; called by muse, mutect2, varscan2
- RIMS1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV53442254; called by muse, mutect2, varscan2
- RIMS2 | c.1875del p.G626Efs*3 (on ENST00000666250 / NM_001348490.2; = p.G434Efs*3 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 95/266 reads (36%) | catalogued as rs1282720554; called by mutect2, pindel, varscan2
- RIMS3 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV65503988; called by muse, mutect2, varscan2
- RMC1 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52570753; called by muse, mutect2, varscan2
- RMDN2 | c.655C>T p.R219* (on ENST00000354545 / NM_001322212.2; = p.R397* on NM_144713.5) | Nonsense Mutation (SNP) | VAF 154/418 reads (37%) | catalogued as rs141660653; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 94/248 reads (38%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF138 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as COSV55233454; called by muse, mutect2, varscan2
- RNF152 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs768728944, COSV57184144; called by muse, mutect2, varscan2
- RNF169 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs201694897, COSV55132777; called by mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 16/29 reads (55%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF6 | c.1778dup p.L593Ffs*4 | Frame Shift Ins (INS) | VAF 64/325 reads (20%) | catalogued as rs1199638878; called by mutect2, varscan2
- RNFT1 | c.121A>G p.N41D | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV59869305; called by muse, mutect2, varscan2
- ROS1 | c.1087dup p.Y363Lfs*25 | Frame Shift Ins (INS) | VAF 63/210 reads (30%) | catalogued as rs1392239785; called by mutect2, pindel, varscan2
- RTCA | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 31/562 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1417453268, COSV99559616; called by muse, mutect2
- RUNX1T1 | c.371G>A p.S124N (on ENST00000265814 / NM_001198628.1; = p.S97N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 165/346 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs866831301, COSV56139397; called by muse, mutect2, varscan2
- RXFP3 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs763280924, COSV57504350; called by muse, mutect2, varscan2
- RYK | c.1698G>T p.Q566H (on ENST00000620660 / NM_001005861.2; = p.Q563H on NM_002958.4) | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV56061003; called by muse, mutect2, varscan2
- RYR1 | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as rs142548565, CM157084, COSV100615557; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S1PR1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as rs528925521, COSV59512513; called by muse, mutect2, varscan2
- SASH1 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769499189, COSV66559322; called by muse, mutect2, varscan2
- SC5D | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 77/256 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs745380178, COSV50612677; called by muse, mutect2, varscan2
- SCAF8 | c.3404G>A p.G1135D | Missense Mutation (SNP) | VAF 44/384 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV65790445; called by muse, mutect2, varscan2
- SCN5A | c.5971C>T p.R1991W (on ENST00000333535 / NM_198056.3; = p.R1990W on NM_000335.5) | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs371308670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCTR | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 53/152 reads (35%) | catalogued as COSV50027041; called by muse, mutect2, varscan2
- SCUBE3 | c.1928C>T p.T643M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs531556751, COSV51455257; called by muse, mutect2, varscan2
- SDK2 | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV66182215; called by muse, mutect2, varscan2
- SEC16A | c.6971C>T p.A2324V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV99256578; called by muse, mutect2
- SEMA6A | c.2431C>A p.H811N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99145592; called by muse, varscan2
- SEPTIN1 | c.518G>A p.R173Q (on ENST00000321367; = p.R126Q on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs747998291, COSV58442404; called by muse, mutect2, varscan2
- SEPTIN12 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs995986970, COSV51615739, COSV51615778; called by muse, mutect2, varscan2
- SETD5 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1181303388, COSV56708151; called by muse, mutect2, varscan2
- SFMBT2 | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 107/380 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs535158127, COSV62806184; called by muse, mutect2, varscan2
- SFRP4 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.624); catalogued as COSV52258573, COSV99554731; called by muse, mutect2, varscan2
- SGMS2 | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 500/1518 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62988932; called by muse, varscan2
- SGSM1 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.462); catalogued as COSV68509059; called by muse, mutect2, varscan2
- SH3BP4 | c.1348T>C p.Y450H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100749042; called by muse, mutect2
- SHCBP1 | c.492G>T p.E164D | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV57646557; called by muse, mutect2, varscan2
- SHTN1 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 394/1090 reads (36%) | catalogued as rs746883321, COSV53380072; called by muse, varscan2
- SIDT2 | c.2269G>A p.V757M | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761384595, COSV54055552; called by muse, mutect2, varscan2
- SLC10A2 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145541774; called by muse, mutect2, varscan2
- SLC12A3 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs79351185, CM002107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC13A2 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV58993078; called by muse, mutect2, varscan2
- SLC1A7 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 30/118 reads (25%) | catalogued as COSV65198338; called by muse, mutect2, varscan2
- SLC24A5 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 141/306 reads (46%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs189224179, COSV58319049; called by muse, mutect2, varscan2
- SLC2A4 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs766922260, COSV50300479; called by muse, mutect2
- SLC44A1 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 152/404 reads (38%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.817); catalogued as rs540159903, COSV58262534; called by muse, mutect2, varscan2
- SLC44A5 | c.92T>A p.V31D | Missense Mutation (SNP) | VAF 111/293 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV63759087; called by muse, mutect2, varscan2
- SLC4A7 | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560270432, COSV55394298; called by muse, mutect2, varscan2
- SLC7A2 | c.1465C>T p.Q489* (on ENST00000494857 / NM_001370338.1; = p.Q528* on NM_003046.6) | Nonsense Mutation (SNP) | VAF 87/235 reads (37%) | catalogued as COSV50248214; called by muse, mutect2, varscan2
- SLC8A1 | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV60472683; called by muse, mutect2, varscan2
- SLC9A2 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 167/345 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52129352; called by muse, mutect2, varscan2
- SLCO1B1 | c.260T>C p.F87S | Missense Mutation (SNP) | VAF 1265/3206 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57007863; called by muse, mutect2, varscan2
- SLIT3 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 89/288 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766150043, COSV60595120; called by muse, mutect2, varscan2
- SLITRK1 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.49); catalogued as COSV65674509; called by muse, mutect2, varscan2
- SLITRK4 | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62022440; called by muse, mutect2, varscan2
- SLX4 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 52/528 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs373586019; ClinVar: uncertain significance; called by muse, mutect2
- SNAI1 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54863663; called by muse, mutect2, varscan2
- SNRNP200 | c.6334G>A p.A2112T | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs1460114569, COSV55530393; called by muse, mutect2, varscan2
- SNX14 | c.2242A>G p.S748G (on ENST00000314673 / NM_001350535.1; = p.S695G on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 229/636 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as COSV59010023; called by muse, mutect2, varscan2
- SP140 | c.1415C>T p.T472M | Missense Mutation (SNP) | VAF 87/228 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs919740087, COSV59446924; called by muse, mutect2, varscan2
- SPAG6 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 115/344 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV57618328, COSV57618340; called by muse, mutect2, varscan2
- SPRR1A | c.206T>C p.V69A | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as COSV61080956; called by muse, mutect2, varscan2
- SRCAP | c.857-1G>A p.X286_splice | Splice Site (SNP) | VAF 32/68 reads (47%) | catalogued as COSV99349512; called by muse, mutect2, varscan2
- SRCAP | c.4210C>T p.P1404S | Missense Mutation (SNP) | VAF 286/724 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV52668429; called by muse, mutect2, varscan2
- SSBP2 | c.152del p.N51Tfs*54 | Frame Shift Del (DEL) | VAF 66/178 reads (37%) | catalogued as rs1057518330; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- STARD8 | c.2618dup p.A874Sfs*16 | Frame Shift Ins (INS) | VAF 6/13 reads (46%) | catalogued as rs761897392; called by mutect2, varscan2
- STAT2 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 129/320 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); catalogued as COSV100028665; called by muse, mutect2, varscan2
- STK4 | c.138A>C p.K46N | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65669529; called by muse, mutect2, varscan2
- STRN4 | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs560915215, COSV54416450; called by muse, mutect2, varscan2
- SVEP1 | c.1800G>T p.K600N | Missense Mutation (SNP) | VAF 358/968 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV57030621; called by muse, mutect2, varscan2
- SYTL1 | c.1348G>A p.V450M (on ENST00000543823; = p.V438M on NM_032872.3) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs148530866; called by muse, mutect2
- SZT2 | c.5854C>T p.Q1952* (on ENST00000634258 / NM_001365999.1; = p.Q1895* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 56/182 reads (31%) | catalogued as rs761496842, COSV65167736; called by muse, mutect2, varscan2
- TADA1 | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV63309913; called by muse, mutect2, varscan2
- TAF2 | c.3289C>T p.P1097S | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs1288695761, COSV65416961; called by muse, mutect2, varscan2
- TBC1D25 | c.1984C>T p.R662W | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100952131, COSV65123320; called by muse, mutect2, varscan2
- TCFL5 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as rs778322425, COSV53895612; called by muse, mutect2, varscan2
- TCHH | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | PolyPhen benign (0); catalogued as COSV64273309; called by muse, mutect2, varscan2
- TDRP | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs535067461, COSV60704832; called by muse, mutect2, varscan2
- TENM1 | c.7586C>T p.A2529V | Missense Mutation (SNP) | VAF 79/217 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as rs1288507625, COSV64426298; called by muse, mutect2, varscan2
- TENM3 | c.2321A>G p.D774G | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.266); catalogued as COSV69300424; called by muse, mutect2, varscan2
- TENM3 | c.5753dup p.E1919Gfs*37 | Frame Shift Ins (INS) | VAF 8/27 reads (30%) | catalogued as rs759002897; called by mutect2, varscan2
- TENT5B | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56692473; called by muse, mutect2, varscan2
- TEX10 | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as COSV66514464; called by muse, mutect2, varscan2
- TEX14 | c.2429G>T p.G810V (on ENST00000240361 / NM_001201457.2; = p.G804V on NM_031272.5) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV53612748; called by muse, mutect2, varscan2
- TFAP2B | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 79/241 reads (33%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.954); catalogued as COSV53825520; called by muse, mutect2, varscan2
- TFAP2D | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV50409330; called by muse, varscan2
- TFRC | c.2092C>T p.R698* | Nonsense Mutation (SNP) | VAF 40/283 reads (14%) | catalogued as rs373764388, COSV100786629; called by muse, mutect2, varscan2
- THOC1 | c.144dup p.C49Mfs*4 | Frame Shift Ins (INS) | VAF 32/92 reads (35%) | catalogued as rs746975641; called by mutect2, varscan2
- THRA | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV52841019; called by muse, mutect2, varscan2
- THRAP3 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 44/152 reads (29%) | catalogued as COSV63566841; called by muse, mutect2
- THRAP3 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as rs773025397, COSV57175656; called by muse, mutect2, varscan2
- TMC1 | c.1177T>A p.F393I | Missense Mutation (SNP) | VAF 26/586 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99918827; called by muse, mutect2
- TMCO6 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52799184; called by muse, mutect2, varscan2
- TMEM156 | c.49T>C p.F17L | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV60744030; called by muse, mutect2, varscan2
- TMEM165 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 121/249 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59400641; called by muse, mutect2, varscan2
- TMEM176B | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV50240328; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 30/88 reads (34%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNPO1 | c.2530del p.C844Vfs*45 | Frame Shift Del (DEL) | VAF 151/423 reads (36%) | catalogued as rs757314136; called by mutect2, pindel, varscan2
- TNR | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 159/501 reads (32%) | catalogued as COSV54873507, COSV54891671; called by muse, mutect2, varscan2
- TNRC6C | c.1844del p.N615Mfs*45 | Frame Shift Del (DEL) | VAF 31/114 reads (27%) | catalogued as rs867658870, COSV56951956; called by mutect2, varscan2
- TNS4 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 117/289 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54183667; called by muse, mutect2, varscan2
- TNXB | c.7834A>C p.N2612H (on ENST00000647633; = p.N2365H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1195935577; called by muse, mutect2
- TPCN1 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59233053; called by muse, mutect2, varscan2
- TPST2 | c.1009C>A p.P337T | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV58678528; called by muse, mutect2, varscan2
- TRIM10 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs370225840; called by muse, mutect2, varscan2
- TRIM9 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.388); catalogued as COSV100030793; called by muse, mutect2, varscan2
- TRPM1 | c.455T>G p.L152W | Missense Mutation (SNP) | VAF 121/320 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56631268; called by muse, mutect2, varscan2
- TRPM6 | c.2802T>A p.F934L | Missense Mutation (SNP) | VAF 135/315 reads (43%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV62503881; called by muse, mutect2, varscan2
- TRPM6 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV62503886; called by muse, mutect2, varscan2
- TRPV5 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs387907544, COSV54683255; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSHZ1 | c.2777G>T p.R926M (on ENST00000580243 / NM_001308210.2; = p.R881M on NM_005786.6) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59006314; called by muse, mutect2, varscan2
- TSPO2 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs750976131, COSV55109169; called by muse, mutect2, varscan2
- TSSK3 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs777528015, COSV100345063, COSV61981396; called by muse, mutect2, varscan2
- TTBK1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as rs771750279, COSV52488754; called by muse, mutect2, varscan2
- TTN | c.102764C>T p.P34255L (on ENST00000591111; = p.P26831L on NM_003319.4) | Missense Mutation (SNP) | VAF 111/226 reads (49%) | PolyPhen possibly damaging (0.851); catalogued as rs767565621, COSV59900627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBGCP3 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 63/349 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56184665; called by muse, mutect2, varscan2
- TUFT1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as rs754728864, COSV61948003; called by muse, mutect2, varscan2
- TUT4 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 474/1415 reads (33%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV57110694; called by muse, mutect2, varscan2
- TUT7 | c.4402C>T p.Q1468* | Nonsense Mutation (SNP) | VAF 45/147 reads (31%) | catalogued as COSV52893762; called by muse, mutect2, varscan2
- UHRF2 | c.1106A>T p.Y369F | Missense Mutation (SNP) | VAF 812/2162 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as rs773132991, COSV52791057; called by muse, mutect2, varscan2
- UNC13C | c.4234C>T p.R1412C | Missense Mutation (SNP) | VAF 84/798 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs370227736; called by muse, varscan2
- UQCRC1 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs929204697, COSV52551003; called by muse, mutect2, varscan2
- UROC1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as rs1338435550, COSV52032518, COSV99330978; called by muse, mutect2, varscan2
- USH2A | c.2461G>A p.V821I | Missense Mutation (SNP) | VAF 209/589 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV56334893; called by muse, mutect2, varscan2
- USP11 | c.856G>A p.A286T (on ENST00000218348; = p.A243T on NM_001371072.1) | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1001120579, COSV54472556; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | catalogued as rs764735138; called by mutect2, varscan2
- USP36 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 351/782 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs199873425, COSV61750412; called by muse, mutect2, varscan2
- VAMP5 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 182/449 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs193102078; called by muse, mutect2, varscan2
- VAV1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 104/579 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs771269172, COSV58378743; called by muse, mutect2, varscan2
- VCP | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV62722152; called by muse, mutect2
- VPS11 | c.106G>A p.D36N (on ENST00000620429; = p.D580N on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.194); catalogued as rs782510678, COSV56184051; called by muse, mutect2, varscan2
- VPS41 | c.1163del p.N388Ifs*15 | Frame Shift Del (DEL) | VAF 52/237 reads (22%) | catalogued as rs757692785; called by mutect2, pindel, varscan2
- VPS54 | c.1372T>C p.F458L | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55438180; called by muse, mutect2, varscan2
- VSTM4 | c.604C>A p.Q202K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV60524730; called by muse, mutect2, varscan2
- WAPL | c.3297G>T p.E1099D | Missense Mutation (SNP) | VAF 109/267 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53932771; called by muse, mutect2, varscan2
- WEE1 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55196461; called by muse, mutect2, varscan2
- WEE1 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.321); catalogued as COSV55196471, COSV55196495; called by muse, mutect2, varscan2
- WNT11 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778229304, COSV59443151, COSV59444445; called by muse, mutect2, varscan2
- WSCD2 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54578847; called by muse, mutect2
- WWP1 | c.2503G>A p.V835M | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV55356872; called by muse, mutect2, varscan2
- XKR3 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV58885010; called by muse, mutect2, varscan2
- XRCC2 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 79/257 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100831585; called by muse, mutect2, varscan2
- YIF1B | c.310A>G p.I104V (on ENST00000339413 / NM_001039673.3; = p.I89V on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.224); catalogued as COSV100007821; called by muse, mutect2, varscan2
- YLPM1 | c.686A>G p.Q229R | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV53107219; called by muse, mutect2, varscan2
- YWHAE | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs777592060, COSV51981020; called by muse, mutect2, varscan2
- ZDBF2 | c.5228C>T p.P1743L | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs201499131, COSV65622626; called by muse, mutect2, varscan2
- ZFAT | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs374372896, COSV64735305; called by muse, varscan2
- ZFHX3 | c.470G>T p.C157F | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.457); catalogued as COSV51710737; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1211A>G p.Y404C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767784122, COSV60155811; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1286G>A p.S429N | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs769212506, COSV52851694; called by muse, mutect2, varscan2
- ZMIZ2 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 110/362 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54806289; called by muse, varscan2
- ZMYM3 | c.3068A>G p.E1023G | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV58736403; called by muse, mutect2, varscan2
- ZNF142 | c.1540C>T p.R514W (on ENST00000411696 / NM_001379660.1; = p.R314W on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs537151479, COSV68743074; called by muse, mutect2, varscan2
- ZNF217 | c.2948T>C p.V983A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.6); catalogued as COSV56594517; called by muse, mutect2, varscan2
- ZNF264 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54040929; called by muse, mutect2, varscan2
- ZNF311 | c.1713G>T p.R571S | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as COSV101014084; called by muse, mutect2
- ZNF334 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV61618061; called by muse, mutect2, varscan2
- ZNF354A | c.1487G>A p.C496Y | Missense Mutation (SNP) | VAF 89/269 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59982307; called by muse, mutect2, varscan2
- ZNF407 | c.3163G>A p.A1055T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs753831305, COSV99995077; called by muse, mutect2, varscan2
- ZNF41 | c.2243C>A p.A748D | Missense Mutation (SNP) | VAF 60/982 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.075); catalogued as COSV100491892; called by muse, mutect2
- ZNF420 | c.1070A>G p.H357R | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58492891; called by muse, mutect2, varscan2
- ZNF502 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 110/240 reads (46%) | catalogued as COSV56072670, COSV99939555; called by muse, mutect2, varscan2
- ZNF578 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1217654230, COSV69736053; called by muse, mutect2, varscan2
- ZNF611 | c.1178C>T p.T393I | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60539699; called by muse, mutect2, varscan2
- ZNF619 | c.1617dup p.Q540Sfs*70 | Frame Shift Ins (INS) | VAF 40/126 reads (32%) | catalogued as rs1372461671; called by mutect2, varscan2
- ZNF625 | c.480del p.K161Nfs*23 | Frame Shift Del (DEL) | VAF 67/194 reads (35%) | catalogued as COSV63242073; called by mutect2, pindel, varscan2
- ZNF689 | c.777A>C p.K259N | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54907900; called by muse, mutect2, varscan2
- ZNF71 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100045681; called by muse, mutect2, varscan2
- ZNF792 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as rs144100790, COSV68694018; called by muse, mutect2, varscan2
- ZP4 | c.1142G>A p.W381* | Nonsense Mutation (SNP) | VAF 80/218 reads (37%) | catalogued as rs147749240; called by muse, mutect2, varscan2
- ZPBP | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 104/289 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766035633, COSV50422864; called by muse, mutect2, varscan2
- AGFG2 | c.834del p.P279Qfs*118 | Frame Shift Del (DEL) | VAF 76/232 reads (33%) | called by mutect2, pindel, varscan2
- AHDC1 | c.1758del p.K586Nfs*37 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- ALDH1A3 | c.392dup p.I132Hfs*8 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- AMER1 | c.2252dup p.E752* | Frame Shift Ins (INS) | VAF 219/660 reads (33%) | called by mutect2, pindel, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 25/198 reads (13%) | called by mutect2, varscan2
- ARHGAP20 | c.19del p.Q7Sfs*5 | Frame Shift Del (DEL) | VAF 20/35 reads (57%) | called by mutect2, pindel
- ARL2BP | c.457_459del p.S153del | In Frame Del (DEL) | VAF 54/152 reads (36%) | called by pindel, varscan2
- ASH1L | c.3665del p.K1222Rfs*11 | Frame Shift Del (DEL) | VAF 43/148 reads (29%) | called by mutect2, varscan2
- ATAD2 | c.1379del p.P460Qfs*32 | Frame Shift Del (DEL) | VAF 74/214 reads (35%) | called by mutect2, pindel, varscan2
- ATCAY | c.333dup p.N112Efs*117 | Frame Shift Ins (INS) | VAF 26/164 reads (16%) | called by mutect2, pindel, varscan2
- ATP8B4 | c.3445C>T p.R1149* | Nonsense Mutation (SNP) | VAF 22/786 reads (3%) | called by muse, mutect2
- C1R | c.689del p.P230Lfs*100 (on ENST00000536053 / NM_001354346.2; = p.P216Lfs*100 on NM_001733.7) | Frame Shift Del (DEL) | VAF 25/82 reads (30%) | called by mutect2, pindel, varscan2
- C3 | c.3021del p.S1008Rfs*8 | Frame Shift Del (DEL) | VAF 84/246 reads (34%) | called by mutect2, pindel, varscan2
- CACNG2 | c.966dup p.V323Rfs*62 | Frame Shift Ins (INS) | VAF 40/85 reads (47%) | called by mutect2, pindel, varscan2
- CAMSAP1 | c.1897del p.Q633Sfs*8 | Frame Shift Del (DEL) | VAF 23/88 reads (26%) | called by mutect2, pindel, varscan2
- CCDC47 | c.146_147dup p.V50Lfs*10 | Frame Shift Ins (INS) | VAF 108/326 reads (33%) | called by mutect2, pindel, varscan2
- CCDC9 | c.1371del p.T458Pfs*51 | Frame Shift Del (DEL) | VAF 46/111 reads (41%) | called by mutect2, pindel, varscan2
- CEP128 | c.2245del p.I749Ffs*9 | Frame Shift Del (DEL) | VAF 114/339 reads (34%) | called by mutect2, pindel, varscan2
- CFAP45 | c.1400del p.K467Rfs*59 | Frame Shift Del (DEL) | VAF 110/392 reads (28%) | called by mutect2, pindel, varscan2
- CHD4 | c.4172dup p.L1391Ffs*9 (on ENST00000357008 / NM_001363606.2; = p.L1404Ffs*9 on NM_001273.5) | Frame Shift Ins (INS) | VAF 29/83 reads (35%) | called by mutect2, pindel, varscan2
- CNGA3 | c.1116del p.V373* | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- DAPK1 | c.3822del p.Y1275Tfs*31 | Frame Shift Del (DEL) | VAF 17/39 reads (44%) | called by mutect2, varscan2
- DHX9 | c.3803G>A p.G1268D | Missense Mutation (SNP) | VAF 25/782 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.358); called by muse, mutect2
- DIS3L2 | c.1545del p.I516Ffs*15 | Frame Shift Del (DEL) | VAF 77/206 reads (37%) | called by mutect2, pindel, varscan2
- EOMES | c.1868del p.P623Lfs*6 | Frame Shift Del (DEL) | VAF 89/269 reads (33%) | called by mutect2, pindel, varscan2
- FAM163A | c.398del p.G133Dfs*15 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | called by mutect2, pindel, varscan2
- FAM187B | c.754del p.L252* | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- FGF9 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 16/571 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.035); called by muse, mutect2
- GAK | c.3398del p.P1133Lfs*23 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.7349del p.K2450Rfs*27 | Frame Shift Del (DEL) | VAF 144/469 reads (31%) | called by mutect2, pindel, varscan2
- GPRIN3 | c.1138del p.Q380Rfs*61 | Frame Shift Del (DEL) | VAF 36/100 reads (36%) | called by mutect2, pindel, varscan2
- GSTCD | c.1874dup p.N625Kfs*2 (on ENST00000360505 / NM_001031720.3; = p.N538Kfs*2 on NM_024751.3) | Frame Shift Ins (INS) | VAF 76/264 reads (29%) | called by mutect2, pindel, varscan2
- HAS2 | c.719del p.G240Efs*6 | Frame Shift Del (DEL) | VAF 141/410 reads (34%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.618dup p.H207Tfs*38 | Frame Shift Ins (INS) | VAF 49/138 reads (36%) | called by mutect2, pindel, varscan2
- HLA-B | c.626del p.P209Qfs*5 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- IGHV3-16 | c.23_24insG p.L10Sfs*11 | Frame Shift Ins (INS) | VAF 89/268 reads (33%) | called by mutect2, pindel, varscan2
- JADE1 | c.1180del p.R394Gfs*20 | Frame Shift Del (DEL) | VAF 97/255 reads (38%) | called by mutect2, pindel
- KDM3B | c.1878del p.K627Nfs*60 | Frame Shift Del (DEL) | VAF 80/244 reads (33%) | called by mutect2, pindel, varscan2
- KHDRBS3 | c.230dup p.L77Ffs*49 | Frame Shift Ins (INS) | VAF 87/261 reads (33%) | called by mutect2, pindel, varscan2
- LHX8 | c.524_525del p.E175Gfs*16 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | called by pindel, varscan2
- LNX2 | c.1119del p.L374Wfs*8 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | called by mutect2, pindel, varscan2
- LRP1B | c.1454del p.G485Afs*56 | Frame Shift Del (DEL) | VAF 92/290 reads (32%) | called by mutect2, pindel, varscan2
- LRRN2 | c.1292del p.P431Qfs*5 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- MACROH2A2 | c.438del p.K147Rfs*53 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, varscan2
- MECOM | c.1536del p.P513Qfs*15 (on ENST00000468789 / NM_001105078.4; = p.P701Qfs*15 on NM_004991.4) | Frame Shift Del (DEL) | VAF 364/1169 reads (31%) | called by mutect2, pindel, varscan2
- MSANTD3 | c.584del p.K195Rfs*18 | Frame Shift Del (DEL) | VAF 53/141 reads (38%) | called by mutect2, pindel, varscan2
- MYO15A | c.6733del p.E2245Kfs*8 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, varscan2
- MYO1B | c.1806dup p.A603Sfs*37 | Frame Shift Ins (INS) | VAF 77/214 reads (36%) | called by mutect2, pindel, varscan2
- NAALAD2 | c.795del p.E266Nfs*50 | Frame Shift Del (DEL) | VAF 48/141 reads (34%) | called by pindel, varscan2
- NUTM1 | c.1556del p.G519Afs*26 | Frame Shift Del (DEL) | VAF 63/185 reads (34%) | called by mutect2, pindel, varscan2
- OR6C4 | c.*4del | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- OR7C1 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | called by mutect2, pindel, varscan2
- ORC3 | c.104del p.N35Mfs*15 | Frame Shift Del (DEL) | VAF 90/238 reads (38%) | called by mutect2, pindel, varscan2
- OSBPL5 | c.1213_1215dup p.D405dup | In Frame Ins (INS) | VAF 24/51 reads (47%) | called by mutect2, pindel, varscan2
- PDC | c.639del p.F213Lfs*9 | Frame Shift Del (DEL) | VAF 34/140 reads (24%) | called by mutect2, varscan2
- PEAK1 | c.2587del p.Q863Kfs*186 | Frame Shift Del (DEL) | VAF 402/977 reads (41%) | called by mutect2, pindel, varscan2
- PGC | c.295dup p.V99Gfs*48 | Frame Shift Ins (INS) | VAF 33/121 reads (27%) | called by mutect2, pindel, varscan2
- PIWIL4 | c.611A>G p.Q204R | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.061); called by muse, mutect2
- PLEKHA4 | c.1843dup p.R615Pfs*17 | Frame Shift Ins (INS) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- PMS1 | c.1406del p.N469Mfs*7 | Frame Shift Del (DEL) | VAF 30/81 reads (37%) | called by mutect2, pindel, varscan2
- PRPF38B | c.1461del p.K487Nfs*44 | Frame Shift Del (DEL) | VAF 41/126 reads (33%) | called by mutect2, pindel, varscan2
- PSG3 | c.20del p.P7Lfs*19 | Frame Shift Del (DEL) | VAF 117/328 reads (36%) | called by mutect2, pindel, varscan2
- PTOV1 | c.1248del p.*417Sfs*14 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel
- PTPN4 | c.963del p.F321Lfs*7 | Frame Shift Del (DEL) | VAF 199/569 reads (35%) | called by mutect2, pindel, varscan2
- RANBP10 | c.74del p.G25Afs*11 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, varscan2
- RBM15 | c.2729del p.G910Afs*41 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- RGS3 | c.1964_1966del p.K655del (on ENST00000350696 / NM_001282923.2; = p.K543del on NM_017790.4) | In Frame Del (DEL) | VAF 14/43 reads (33%) | called by pindel, varscan2
- RHOT1 | c.1283del p.N428Tfs*16 | Frame Shift Del (DEL) | VAF 166/452 reads (37%) | called by mutect2, pindel, varscan2
- RLF | c.1010del p.L337Wfs*10 | Frame Shift Del (DEL) | VAF 150/450 reads (33%) | called by mutect2, pindel, varscan2
- RPGRIP1 | c.2696del p.N899Mfs*38 | Frame Shift Del (DEL) | VAF 42/98 reads (43%) | called by mutect2, pindel, varscan2
- RPL22 | c.267del p.K89Nfs*3 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | called by mutect2, pindel, varscan2
- RPRD2 | c.4194del p.L1399Wfs*14 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | called by mutect2, pindel, varscan2
- SCN5A | c.3024del p.Y1009Tfs*136 (on ENST00000333535 / NM_198056.3; = p.Y1009Tfs*135 on NM_000335.5) | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | called by mutect2, pindel, varscan2
- SEL1L3 | c.391del p.R131Gfs*15 | Frame Shift Del (DEL) | VAF 70/208 reads (34%) | called by mutect2, pindel, varscan2
- SF1 | c.221del p.P74Lfs*63 | Frame Shift Del (DEL) | VAF 69/196 reads (35%) | called by mutect2, pindel, varscan2
- SLC25A14 | c.942del p.F314Lfs*7 | Frame Shift Del (DEL) | VAF 513/1420 reads (36%) | called by mutect2, pindel, varscan2
- SMAD4 | c.94_95del p.S32* | Frame Shift Del (DEL) | VAF 56/166 reads (34%) | called by pindel, varscan2
- SPHKAP | c.4458dup p.D1487* | Frame Shift Ins (INS) | VAF 137/405 reads (34%) | called by mutect2, pindel, varscan2
- STAG2 | c.363del p.F121Lfs*24 | Frame Shift Del (DEL) | VAF 149/500 reads (30%) | called by mutect2, pindel, varscan2
- STAT6 | c.2444del p.G815Efs*27 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | called by mutect2, pindel
- STAU2 | c.1469dup p.C491Lfs*31 (on ENST00000524300 / NM_001164380.2; = p.C459Lfs*24 on NM_014393.2) | Frame Shift Ins (INS) | VAF 127/391 reads (32%) | called by mutect2, pindel, varscan2
- STT3A | c.317del p.F106Sfs*45 | Frame Shift Del (DEL) | VAF 401/1131 reads (35%) | called by mutect2, pindel, varscan2
- SYNM | c.2346del p.L783Wfs*36 | Frame Shift Del (DEL) | VAF 45/146 reads (31%) | called by mutect2, pindel, varscan2
- TET3 | c.4152del p.F1385Lfs*17 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- TOP2B | c.4321dup p.S1441Kfs*20 (on ENST00000264331 / NM_001330700.2; = p.S1436Kfs*20 on NM_001068.3) | Frame Shift Ins (INS) | VAF 49/162 reads (30%) | called by mutect2, varscan2
- TRMT13 | c.39del p.P14Qfs*48 | Frame Shift Del (DEL) | VAF 90/309 reads (29%) | called by mutect2, pindel, varscan2
- TSC22D1 | c.2543dup p.T849Nfs*19 | Frame Shift Ins (INS) | VAF 22/88 reads (25%) | called by pindel, varscan2
- TSPYL5 | c.401del p.N134Mfs*30 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | called by mutect2, varscan2
- TTN | c.32768del p.K10923Rfs*104 (on ENST00000591111; = p.K9996Rfs*104 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 332/1007 reads (33%) | called by mutect2, pindel, varscan2
- UGT2A1 | c.290del p.N97Ifs*18 | Frame Shift Del (DEL) | VAF 157/487 reads (32%) | called by mutect2, pindel, varscan2
- USP11 | c.1963dup p.D655Gfs*2 (on ENST00000218348; = p.D612Gfs*2 on NM_001371072.1) | Frame Shift Ins (INS) | VAF 33/117 reads (28%) | called by mutect2, pindel, varscan2
- VWA5A | c.1857dup p.L620Ifs*16 | Frame Shift Ins (INS) | VAF 59/177 reads (33%) | called by mutect2, pindel, varscan2
- WDR19 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- ZNF644 | c.579del p.K193Nfs*16 | Frame Shift Del (DEL) | VAF 47/133 reads (35%) | called by mutect2, pindel, varscan2
- ZWILCH | c.954del p.D319Tfs*7 | Frame Shift Del (DEL) | VAF 42/331 reads (13%) | called by mutect2, pindel, varscan2
- A4GALT | c.822C>T p.R274= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as rs372559008; called by muse, mutect2, varscan2
- ABCB1 | c.1608G>A p.K536= | Silent (SNP) | VAF 116/311 reads (37%) | catalogued as COSV55946293; called by muse, mutect2, varscan2
- ABLIM2 | c.375C>T p.N125= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs768221546, COSV56399662; called by muse, mutect2, varscan2
- AC231657.3 | c.750G>A p.V250= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as COSV59875508; called by muse, mutect2, varscan2
- ACOT9 | c.738G>A p.T246= | Silent (SNP) | VAF 80/324 reads (25%) | catalogued as rs1406726852, COSV60537017; called by muse, varscan2
- ACOX3 | c.1275G>A p.A425= | Silent (SNP) | VAF 44/58 reads (76%) | catalogued as rs753101879, COSV62711039; called by muse, mutect2, varscan2
- ADAM11 | c.2262G>A p.T754= | Silent (SNP) | VAF 50/92 reads (54%) | catalogued as rs575543165, COSV52344884; called by muse, mutect2
- ADAMTS14 | c.3333G>A p.L1111= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs1285027025, COSV100941432; called by mutect2, varscan2
- ADARB1 | c.1179C>T p.C393= | Silent (SNP) | VAF 65/188 reads (35%) | catalogued as COSV62342407; called by muse, mutect2, varscan2
- ADRA2C | c.654C>A p.S218= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV57466852; called by muse, mutect2, varscan2
- AHCTF1 | c.1380C>T p.C460= (on ENST00000366508; = p.C434= on NM_015446.5) | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100403241; called by muse, mutect2
- AKAP8 | c.1914C>T p.G638= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs538149553, COSV54101316; called by muse, mutect2, varscan2
- AL136295.1 | c.1284G>A p.R428= | Silent (SNP) | VAF 42/138 reads (30%) | catalogued as COSV55778428; called by muse, mutect2, varscan2
- AMIGO1 | c.108C>T p.A36= | Silent (SNP) | VAF 4/7 reads (57%) | catalogued as rs985026706, COSV63990262; called by mutect2, varscan2
- ANGPT2 | c.888C>A p.G296= | Silent (SNP) | VAF 450/1293 reads (35%) | catalogued as COSV100290680; called by muse, mutect2, varscan2
- ANGPT2 | c.603G>A p.K201= | Silent (SNP) | VAF 151/462 reads (33%) | catalogued as COSV100290690; called by muse, mutect2, varscan2
- ANOS1 | c.681C>A p.I227= | Silent (SNP) | VAF 199/408 reads (49%) | catalogued as COSV52916611; called by muse, mutect2, varscan2
- AOX1 | c.12G>A p.A4= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV63414152; called by muse, mutect2, varscan2
- AP1B1 | c.156C>T p.P52= | Silent (SNP) | VAF 56/143 reads (39%) | catalogued as rs755546030, COSV58014987; called by muse, mutect2, varscan2
- AQP8 | c.216C>T p.H72= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs138117795; called by muse, mutect2, varscan2
- AR | c.1918C>T p.L640= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as COSV65953617; called by muse, varscan2
207 further variants in this file (0 protein-altering or splice-affecting, 193 silent, 14 other) are not listed here.
